Somatic mutation profile of tumor specimen 0DU7A8 from CCDI case PBCKRA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.0 years (6,579 days).
Specimen 0DU7A8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bfd945b-6fa3-4fde-b131-0a6df8c75f1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU7A6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3ccd1ef-59f8-48f1-9ad9-5fedcecc2e77

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 3, 3'UTR 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 444/1752 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 576/2038 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 642/971 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KCNH2 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 265/594 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as rs1479831528; called by muse, varscan2
- NPIPB7 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 80/458 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs1180754469; called by muse, varscan2
- PALM3 | c.1858G>A p.E620K (on ENST00000340790; = p.E635K on NM_001145028.2) | Missense Mutation (SNP) | VAF 292/664 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs941395907, COSV54600333; called by muse, varscan2
- VPS36 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 330/1015 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs752241758, COSV100955246; called by muse, varscan2
- ACSM4 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 480/1348 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, varscan2
- AIMP1 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 890/2328 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, varscan2
- NOLC1 | c.1243A>C p.K415Q | Missense Mutation (SNP) | VAF 556/926 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); called by muse, varscan2
- PTPN4 | c.1264C>G p.H422D | Missense Mutation (SNP) | VAF 286/1932 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.075); called by muse, varscan2
- RAPGEF2 | c.1028A>G p.D343G | Missense Mutation (SNP) | VAF 94/856 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TOX | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 884/2369 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); called by muse, varscan2
- PLXNA1 | c.2148C>T p.Y716= | Silent (SNP) | VAF 744/2020 reads (37%) | catalogued as rs1474443881, COSV52532462; called by muse, varscan2
- IQCF5 | c.*12A>C | 3'UTR (SNP) | VAF 294/688 reads (43%) | called by muse, varscan2
- MROH2B | c.4483-20G>C | Intron (SNP) | VAF 228/1574 reads (14%) | called by muse, varscan2
- PIGR | c.*2C>T | 3'UTR (SNP) | VAF 136/1308 reads (10%) | catalogued as rs372104345; called by muse, varscan2
- SLC2A11 | c.21+42G>A | Intron (SNP) | VAF 163/762 reads (21%) | catalogued as rs1421948582; called by muse, varscan2
- TMEM30B | c.-29G>T | 5'UTR (SNP) | VAF 380/1310 reads (29%) | called by muse, varscan2
- ZNF462 | c.6013-30C>G | Intron (SNP) | VAF 152/378 reads (40%) | called by muse, varscan2
